Gene-level copy-number profile of tumor specimen TCGA-XK-AAIV-01A from TCGA case TCGA-XK-AAIV, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 63.9 years (23,325 days).
Specimen TCGA-XK-AAIV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.9a9c0fe0-c68b-44b2-a4f1-5963240d62c1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XK-AAIV-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f72a28eb-b5cc-4a0d-8d51-9cbf22e8f38a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 16; copy number 1: 256; copy number 2: 13,132; copy number 3: 16,956; copy number 4: 19,410; copy number 5: 7,784; copy number 6: 115; copy number 7: 929; copy number 8: 116; copy number 9: 465; copy number 10: 636.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XK-AAIV-01A-11D-A41J-01): tumor purity 0.24, ploidy 3.51, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–2): PTEN.
- chr10:87,945,502–88,820,546, 15 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,101 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:57,855,500–80,568,506, 333 genes, copy number 9–10 (broad region; genes not listed).
- chr8:86,866,415–99,895,121, 200 genes, copy number 9 (within-gene range 7–9) (broad region; genes not listed).
- chr8:100,004,583–100,004,649, 1 gene, copy number 9: SNORD77B.
- chr8:102,239,394–116,403,757, 147 genes, copy number 9–10 (broad region; genes not listed).
- chr8:117,794,490–119,832,841, 22 genes, copy number 10 (within-gene range 2–10): EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1, COLEC10, AC107953.2, MAL2, MAL2-AS1, MIR548AZ, AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3, ENPP2, CYCSP23, RN7SKP153, TAF2.
- chr8:123,851,987–145,066,685, 398 genes, copy number 10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 249. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
